Somatic mutation profile of tumor specimen TCGA-EL-A4K7-01A (aliquot TCGA-EL-A4K7-01A-11D-A257-08) from TCGA case TCGA-EL-A4K7, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 74.8 years (27,306 days).
Specimen TCGA-EL-A4K7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c4527cf1-ee02-4197-809e-b11b81ae1ea3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A4K7-11A (Solid Tissue Normal), aliquot TCGA-EL-A4K7-11A-11D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef47065d-f3ce-48cc-b74c-28a8f0f25208

The open-access MAF lists 39 somatic variants for this specimen: 33 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 27, Silent 6, Nonsense Mutation 3, Frame Shift Del 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- AGPAT2 | c.437C>G p.S146C | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as rs1252060863, COSV100451956; called by muse, mutect2, varscan2
- AHNAK | c.1885C>T p.P629S | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV99947070; called by muse, mutect2, varscan2
- ARHGAP4 | c.613G>T p.A205S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.044); catalogued as COSV100604010; called by muse, mutect2
- ASB12 | c.714G>C p.E238D | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.88); catalogued as rs1427347854, COSV62857952; called by muse, mutect2, varscan2
- BCOR | c.4009G>T p.E1337* (on ENST00000378444 / NM_001123385.2; = p.E1303* on NM_017745.6) | Nonsense Mutation (SNP) | VAF 7/13 reads (54%) | catalogued as COSV100653088, COSV60720521; called by muse, varscan2
- C2CD3 | c.4289A>G p.H1430R | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.163); catalogued as COSV100486526; called by muse, mutect2, varscan2
- CBR1 | c.760T>G p.L254V | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as COSV99289455; called by muse, mutect2, varscan2
- DNAH2 | c.6944T>A p.M2315K | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1318896671, COSV101209227; called by muse, mutect2, varscan2
- DSP | c.8151G>A p.W2717* | Nonsense Mutation (SNP) | VAF 15/252 reads (6%) | catalogued as COSV100672949; called by muse, mutect2
- ECT2 | c.1819T>A p.L607I (on ENST00000392692 / NM_001349098.2; = p.L576I on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99221254; called by muse, mutect2
- GRIN2B | c.382G>A p.G128R | Missense Mutation (SNP) | VAF 15/249 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101663005; called by muse, mutect2
- HCST | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.031); catalogued as rs759213775, COSV99385582; called by muse, mutect2, varscan2
- HPX | c.1370T>A p.L457H | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV99793305; called by muse, mutect2
- MYOZ2 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755233280, COSV61085447; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOBOX | c.794C>G p.P265R | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV99779391; called by muse, mutect2, varscan2
- OR5M3 | c.294G>T p.Q98H | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100392474, COSV56565938; called by muse, mutect2
- PLXNA2 | c.3995A>T p.H1332L | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65443899; called by muse, mutect2
- PUM2 | c.2138A>G p.D713G | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100163523; called by muse, mutect2, varscan2
- SELENBP1 | c.740G>T p.G247V | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100923632; called by muse, mutect2
- SEPTIN5 | c.548A>G p.N183S | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs768217482, COSV63531101; called by muse, mutect2, varscan2
- SLC38A9 | c.1504A>G p.I502V | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.114); catalogued as COSV100591362; called by muse, mutect2
- SLC52A3 | c.500T>C p.V167A | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV99447828; called by muse, mutect2, varscan2
- SMC1A | c.1607A>G p.K536R | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100447304; called by muse, mutect2
- TYK2 | c.692G>T p.R231L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as COSV53392286, COSV99314631; called by muse, mutect2, varscan2
- UGGT2 | c.2360A>C p.N787T | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV100948640; called by muse, mutect2, varscan2
- USP49 | c.1649G>T p.R550L | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99790128; called by muse, mutect2
- WDR35 | c.2801T>C p.I934T (on ENST00000345530 / NM_001006657.2; = p.I923T on NM_020779.4) | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV99853093; called by muse, mutect2
- ZNF605 | c.1504G>T p.E502* | Nonsense Mutation (SNP) | VAF 13/108 reads (12%) | catalogued as COSV100053531; called by muse, mutect2, varscan2
- CAND1 | c.1402del p.A468Pfs*2 | Frame Shift Del (DEL) | VAF 8/50 reads (16%) | called by mutect2, varscan2
- CAND1 | c.2275_2276del p.F759Pfs*10 | Frame Shift Del (DEL) | VAF 44/140 reads (31%) | called by mutect2, pindel, varscan2
- CAND1 | c.2709del p.R905Gfs*9 | Frame Shift Del (DEL) | VAF 7/64 reads (11%) | called by mutect2, pindel, varscan2
- POLR2A | c.3178C>T p.L1060F | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); called by muse, mutect2
- AK5 | c.579C>A p.A193= (on ENST00000354567 / NM_174858.3; = p.A167= on NM_012093.4) | Silent (SNP) | VAF 8/97 reads (8%) | catalogued as COSV100481448; called by muse, mutect2
- ALG1 | c.1362G>A p.V454= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as rs760747036, COSV99275702; called by muse, mutect2, varscan2
- ESS2 | c.846C>T p.P282= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs938269730, COSV99350811; called by muse, mutect2, varscan2
- LAMA1 | c.711T>C p.D237= | Silent (SNP) | VAF 12/113 reads (11%) | catalogued as COSV67534448; called by muse, mutect2, varscan2
- RPA2 | c.201G>C p.G67= | Silent (SNP) | VAF 16/226 reads (7%) | catalogued as COSV100536157; called by muse, mutect2
- SCRIB | c.4680C>G p.T1560= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100253090; called by muse, mutect2
